Somatic mutation profile of tumor specimen MP2PRT-PAUUGN-TBP1-A (aliquot MP2PRT-PAUUGN-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUUGN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,505 days).
Specimen MP2PRT-PAUUGN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79f30bf6-7d46-46ea-bec8-a6cfbb34f030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUGN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUGN-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d39e69cc-c786-478c-b970-3acec187e290

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRM5 | c.3275C>T p.P1092L (on ENST00000305447 / NM_001143831.2; = p.P1060L on NM_000842.4) | Missense Mutation (SNP) | VAF 39/1172 reads (3%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.709); called by muse, mutect2
- TRAJ13 | c.2T>A p.*1= | Missense Mutation (SNP) | VAF 136/416 reads (33%) | called by muse, mutect2
- TRAJ13 | c.4A>G p.N2D | Missense Mutation (SNP) | VAF 138/424 reads (33%) | called by muse, mutect2
- ITGA11 | c.873C>T p.N291= | Silent (SNP) | VAF 156/380 reads (41%) | catalogued as rs776791415, COSV59875003; called by muse, mutect2, varscan2
- CCDC43 | chr17:44673518 del AGGAGTTCCT | 3'Flank (DEL) | VAF 117/323 reads (36%) | called by mutect2, pindel, varscan2
